Surgical pathology report (de-identified scan), TCGA case TCGA-LK-A4NW, project TCGA-MESO (Mesothelioma), tissue source site University of Pittsburgh, specimen TCGA-LK-A4NW-01A (Primary Tumor).

FINAL DIAGNOSIS:

Collection Date:

PARTS 1 AND 2: SKIN AND CHEST WALL, "CHEST WALL MASS" AND "CHEST WALL MASS DEEP ASPECT",
EXCISION -
FISTULA TRACT ASSOCIATED WITH FOREIGN-BODY GIANT CELL REACTION, GRANULATION TISSUE, FAT
NECROSIS, AND SCAR, ASSOCIATED WITH MALIGNANT MESOTHELIOMA WITHIN THE PERI-FISTULA TRACT
CONNECTIVE TISSUE AND ADIPOSE TISSUE.

PART 3: BONE, 7TH RIB, RESECTION -
PORTIONS OF BONE AND BONE MARROW WITH NO SIGNIFICANT ABNORMALITY.

PART 4: PLEURA, "PLEURAL MASS", BIOPSY -
DIFFUSE MALIGNANT MESOTHELIOMA, TUBULOPAPILLARY TYPE (see comment).

PART 5: BRONCHUS, LEFT SECONDARY CARINA, BIOPSY -
FRAGMENTS OF BRONCHIAL MUCOSA WITH CHRONIC INFLAMMATION. GROCOTT AND TRICHROME
STAINS
ARE NEGATIVE. CORRELATION WITH CULTURE RESULTS SUGGESTED. NO EVIDENCE OF MALIGNANCY.

PART 6: DIAPHRAGM, "DIAPHRAGMATIC NODULE", BIOPSY -
DIFFUSE MALIGNANT MESOTHELIOMA, TUBULOPAPILLARY TYPE.

PART 7: LYMPH NODE, "LEVEL 7 LYMPH NODE", BIOPSY -
A. ONE (1) OF THREE (3) LYMPH NODES WITH MICROSCOPIC SUBCAPSULAR AGGREGATES OF CELLS
CONSISTENT WITH METASTATIC MALIGNANT MESOTHELIOMA.
B. PERI-NODAL SOFT TISSUE IMPLANTS OF MALIGNANT MESOTHELIOMA.

PART 8: PLEURA, "ANTERIOR THYMIC PLEURA", BIOPSY -
DIFFUSE MALIGNANT MESOTHELIOMA ASSOCIATED WITH ACUTE AND ORGANIZING PLEURITIS.

PART 9: LYMPH NODES, "LEVEL 5 LYMPH NODES", BIOPSY -
A. TWO (2) OF FOUR (4) LYMPH NODES WITH SUBCAPSULAR MICROSCOPIC FOCI OF METASTATIC
MALIGNANT MESOTHELIOMA.
B. PERI-NODAL SOFT TISSUE IMPLANTS OF MALIGNANT MESOTHELIOMA.

PARTS 10, 11, 12, 13, 14, 15, 16, 17, 18, 19 AND 20: PLEURA, "PARAPHRENIC MASS", "DIAPHRAGMATIC TUMOR",
"HILAR TISSUE", "TUMOR", "PERICARDIAL FAT PAD", "THYMUS PARAMAMMARY", "THYMUS", "PLEURAL
MASS", "POSTERIOR DIAPHRAGMATIC SULCUS TUMOR", PERICARDIUM, AND "PHRENIC AREA",
BIOPSIES -
DIFFUSE MALIGNANT MESOTHELIOMA ASSOCIATED WITH ACUTE FIBRINOUS AND ORGANIZING PLEURITIS.

COMMENT:

The diffuse malignant mesothelioma shows characteristic tubulopapillary growth pattern, associated with extensive
pleural and angiolymphatic infiltration. Immunostains show a typical pattern of staining for malignant mesothelioma
within neoplastic cells expressing nuclear calretinin, cytokeratin 5/6, thrombomodulin, D2-40, and WT-1, and failing to
express TTF-1, CEA, B72.3, Leu-M1, PSA, thyroglobulin, and CDX-2. Focal expression of BerEP4 is present.
Histochemical stains show glycogen expression with PAS stains, but no intracytoplasmic neutral mucin production with
diastase pre-digestive PAS stains. Overall, this histomorphology and immunophenotype is characteristic of a diffuse
malignant mesothelioma.

Samples of the level-7 and level-5 lymph nodes show occasional cells within the subcapsular sinus of the nodes,
documented by cytokeratin stains. For this reason, we would stage this pleural mesothelioma as a T4N1 malignant
mesothelioma.

Addendum

This case has been reviewed at the
of malignant mesothelioma was confirmed.

where the diagnosis

Addendum

Probe: LSI 9p21/CEP9 Dual Color Probe

Cytogenetic Location: 9p21; Centromere 9. Probe Description: LSI 9p21 dual color DNA probe hybridizes to the band
9p21 and the centromere of chromosome 9. This probe may be useful for the detection of the p16 region associated with
9p21. The SpectrumOrange LSI p16 probe spans approximately 190 kb and contains a number of genetic loci including
D9S1749, D9S1747, p16(INK4A), p14(ARF), D9S1748, p15(INK4B) and D9S1752.

RESULT:

Cells Analyzed: 75

Ratio p16/CEP9: 0.0

% Cells deleted: 100%

Hemizygous loss: 0%

Homozygous loss: 100%

Complex loss: 0%

% Hyperdiploid: 0%

1CB-0-3

Mesothelioma, NOS 9050/13

Site: pleura, NOS C38.4

lw 9/25/12

Diagnostic Discrepancy		
HPV Discrepancy		
Dual/Unichrom Plus Primary Noted		
Caveats (if any)		

These results are much more common in malignant mesothelioma than any other primary pleuropulmonary neoplasm.

Source: NCI Genomic Data Commons file 8bc3ddec-2a21-4f3d-b405-11f0f30bbecd (TCGA-LK-A4NW.9FA130FA-B7F3-44C9-824D-4B332B72CB3E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).